CCDI case PBCIDB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8815d9c4-3b88-4737-a5cd-9f6e4a714b14

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9161/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,306 days).

Biospecimens (3 samples)
- Sample 0DSI7H: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSI88: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSI9V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
